Somatic mutation profile of tumor specimen TCGA-FS-A1ZG-06A (aliquot TCGA-FS-A1ZG-06A-11D-A197-08) from TCGA case TCGA-FS-A1ZG, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 61.1 years (22,329 days).
Specimen TCGA-FS-A1ZG-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ed5d27a-3773-4681-9945-854b485757c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FS-A1ZG-10A (Blood Derived Normal), aliquot TCGA-FS-A1ZG-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f2e71e91-a472-4ccf-9274-53ef44086c58

The open-access MAF lists 36 somatic variants for this specimen: 25 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 20, Silent 11, Nonsense Mutation 4, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 21/23 reads (91%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- APC | c.2510C>G p.S837* | Nonsense Mutation (SNP) | VAF 22/47 reads (47%) | catalogued as rs79512956, CD011083, CD084036, CM014886, COSV57338611, COSV57345932; ClinVar: other; called by muse, mutect2, varscan2
- CPO | c.991G>T p.E331* | Nonsense Mutation (SNP) | VAF 8/19 reads (42%) | catalogued as COSV99786558; called by mutect2, varscan2
- CXXC1 | c.571A>T p.K191* | Nonsense Mutation (SNP) | VAF 17/38 reads (45%) | catalogued as COSV53274072; called by mutect2, varscan2
- DHX30 | c.497G>A p.R166Q (on ENST00000445061 / NM_138615.3; = p.R127Q on NM_014966.3) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.885); catalogued as rs760235118, COSV62394247; called by mutect2, varscan2
- DMD | c.3013G>A p.E1005K | Missense Mutation (SNP) | VAF 22/26 reads (85%) | SIFT tolerated (0.53); PolyPhen benign (0.096); catalogued as COSV63739010, COSV63748696; called by muse, varscan2
- FAM83B | c.1346C>T p.A449V | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.349); catalogued as rs147775708, COSV60921364; called by mutect2, varscan2
- GHR | c.1112A>C p.E371A | Missense Mutation (SNP) | VAF 36/43 reads (84%) | SIFT tolerated (0.72); PolyPhen benign (0.062); catalogued as COSV50110412; called by muse, mutect2, varscan2
- HYI | c.811G>T p.V271L (on ENST00000372434 / NM_001330526.2; = p.V246L on NM_031207.6) | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); catalogued as COSV65094410; called by muse, mutect2, varscan2
- KDM5C | c.1717C>T p.P573S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64772316; called by mutect2, varscan2
- MBD5 | c.3928C>T p.Q1310* | Nonsense Mutation (SNP) | VAF 20/44 reads (45%) | catalogued as COSV68696619; called by mutect2, varscan2
- NIBAN1 | c.64G>C p.E22Q | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as COSV62286255; called by muse, mutect2
- NLRP10 | c.435G>T p.Q145H | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as COSV60779938; called by muse, mutect2, varscan2
- NMRAL1 | c.746T>C p.L249P | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.324); catalogued as COSV52059726; called by muse, mutect2, varscan2
- PDHX | c.889A>C p.T297P | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV57165536; called by muse, mutect2, varscan2
- PIGU | c.742C>G p.L248V | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.893); catalogued as COSV54161970; called by muse, mutect2, varscan2
- SCN5A | c.2528C>A p.T843K | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV100349202, COSV61135233; called by muse, mutect2, varscan2
- SLC22A12 | c.1039C>A p.R347S | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.248); catalogued as rs374858585, CM1110331, COSV60571707; called by muse, mutect2, varscan2
- STK38 | c.889A>G p.T297A | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.142); catalogued as rs753260473, COSV57708549; called by mutect2, varscan2
- TBC1D8B | c.2434T>G p.L812V | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs972416127, COSV52177997; called by muse, varscan2
- TMEM86B | c.292G>A p.V98I | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1221416841, COSV58983948; called by mutect2, varscan2
- TNC | c.4997T>G p.I1666R | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.864); catalogued as COSV60783677; called by muse, mutect2
- UBIAD1 | c.127A>G p.R43G | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV65147673; called by muse, varscan2
- VPS54 | c.1733A>C p.D578A | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV99708331; called by muse, mutect2, varscan2
- HECTD1 | c.3705dup p.L1236Tfs*10 | Frame Shift Ins (INS) | VAF 32/104 reads (31%) | called by pindel, varscan2
- CYLC2 | c.111T>C p.F37= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as COSV66337205; called by muse, mutect2, varscan2
- FER1L6 | c.2154C>T p.D718= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as rs188177034; called by mutect2, varscan2
- FKBP9 | c.1446G>A p.E482= | Silent (SNP) | VAF 16/19 reads (84%) | catalogued as COSV54229902; called by muse, varscan2
- GLP1R | c.682C>T p.L228= | Silent (SNP) | VAF 28/64 reads (44%) | catalogued as COSV64714787; called by muse, mutect2, varscan2
- GPX7 | c.165C>T p.S55= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as rs764261634, COSV63652555; called by mutect2, varscan2
- GRIPAP1 | c.564G>A p.P188= | Silent (SNP) | VAF 14/18 reads (78%) | catalogued as rs781892017, COSV64551758; called by mutect2, varscan2
- HCFC1 | c.753G>A p.A251= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs1557117195, COSV60071151; called by mutect2, varscan2
- MBTD1 | c.1521T>C p.R507= | Silent (SNP) | VAF 57/140 reads (41%) | catalogued as COSV64502729, COSV64503219; called by muse, varscan2
- PCDHB14 | c.978T>C p.G326= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV53387921; called by muse, mutect2
- ST6GALNAC1 | c.324G>A p.P108= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as rs749880748, COSV50074081; called by mutect2, varscan2
- ZBTB1 | c.261T>A p.I87= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as COSV62437842; called by mutect2, varscan2
